Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A870, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A870-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localization: R parieto-occipital

Diagnosis: Anaplastic oligoastrocytoma (grade III WHO)

Name of Pathologist:

ICD-C-3
Oligoastrocytoma, grade III
9382/3
Site: Brain, supratentorial NOS
C71.0
R Brain, overlapping lesion
C71.8
10/20/13

Source: NCI Genomic Data Commons file e7207ec5-f3a3-4fe4-a4ce-339182453e51 (TCGA-QH-A870.C84F6D0C-3879-4D63-8CE8-10D03D3C71A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).